Somatic mutation profile of tumor specimen TCGA-55-6981-01A (aliquot TCGA-55-6981-01A-11D-1945-08) from TCGA case TCGA-55-6981, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 53.4 years (19,497 days).
Specimen TCGA-55-6981-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ec6ebe80-e3ba-4fa2-8ec6-dbe6401125e1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-6981-11A (Solid Tissue Normal), aliquot TCGA-55-6981-11A-01D-1945-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fbee4520-dde8-431b-8e7d-62ea26097dd7

The open-access MAF lists 53 somatic variants for this specimen: 45 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 6, Frame Shift Del 3, Nonsense Mutation 2, RNA 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDK4 | c.71G>T p.R24L | Missense Mutation (SNP) | VAF 14/47 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.687); catalogued as rs104894340, CM980320, COSV56983700, COSV56984378; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- EGFR | c.2240_2254del p.L747_T751del | In Frame Del (DEL) | VAF 108/195 reads (55%) | hotspot (GDC flag); catalogued as rs121913442, COSV51863059; ClinVar: drug response; called by mutect2, pindel, varscan2
- ADAM18 | c.1946G>A p.R649K | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs758696627, COSV55846076; called by muse, mutect2, varscan2
- ATG2B | c.506T>G p.I169R | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as COSV63422682; called by muse, mutect2, varscan2
- BSN | c.5960C>T p.T1987I | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56515986; called by muse, mutect2, varscan2
- CACNA1G | c.2231A>G p.Y744C | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61724383; called by muse, mutect2
- CDYL2 | c.203C>G p.S68* | Nonsense Mutation (SNP) | VAF 25/107 reads (23%) | catalogued as COSV73647612; called by muse, mutect2, varscan2
- COL4A4 | c.4577A>G p.N1526S | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as COSV61631242; called by muse, mutect2
- DHX35 | c.1364C>T p.S455L | Missense Mutation (SNP) | VAF 17/154 reads (11%) | SIFT tolerated (0.82); PolyPhen benign (0.003); catalogued as rs768096287, COSV52673751; called by muse, mutect2, varscan2
- DIAPH3 | c.1932C>G p.I644M (on ENST00000400324 / NM_001042517.2; = p.I381M on NM_030932.3) | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.58); catalogued as COSV57368441; called by muse, mutect2, varscan2
- DSG3 | c.1084C>T p.R362* | Nonsense Mutation (SNP) | VAF 14/63 reads (22%) | catalogued as rs540587123, COSV57125500; called by muse, mutect2, varscan2
- FLOT2 | c.1018C>T p.R340W | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as rs374687353, COSV67529113; called by muse, mutect2, varscan2
- G2E3 | c.1463A>G p.D488G | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52839754; called by muse, mutect2
- GPR35 | c.110T>G p.L37R | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV60576967; called by muse, mutect2
- GRIA3 | c.2317G>C p.A773P | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (1); PolyPhen possibly damaging (0.8); catalogued as COSV52055860; called by muse, mutect2
- HVCN1 | c.29C>T p.T10I | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.31); catalogued as COSV54371730; called by mutect2, varscan2
- IL2RB | c.1354G>A p.E452K | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.147); catalogued as rs933977822, COSV53425881; called by muse, mutect2, varscan2
- IPO4 | c.2395G>A p.V799M | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs747787561, COSV61016253; called by muse, mutect2, varscan2
- ISL1 | c.362C>T p.A121V | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.067); catalogued as rs768220738, COSV57933123; called by mutect2, varscan2
- LPAR4 | c.127G>A p.G43S | Missense Mutation (SNP) | VAF 23/330 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.079); catalogued as COSV70912477; called by muse, mutect2
- LRP4 | c.5497C>T p.R1833W | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.982); catalogued as rs1393617361, COSV66133978; called by mutect2, varscan2
- MOGAT3 | c.247C>T p.R83W | Missense Mutation (SNP) | VAF 33/273 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200165339; called by muse, mutect2, varscan2
- NCOA5 | c.1678C>G p.Q560E | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV51643851; called by mutect2, varscan2
- NSD2 | c.3091G>C p.E1031Q | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.017); catalogued as COSV100374113; called by muse, varscan2
- OGDH | c.472G>T p.D158Y | Missense Mutation (SNP) | VAF 23/203 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.753); catalogued as COSV56048194; called by muse, mutect2, varscan2
- POLR3A | c.1205A>G p.N402S | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.03); catalogued as rs1482405980, COSV64930839; called by muse, mutect2, varscan2
- PPP1R12B | c.500C>T p.P167L | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.045); catalogued as COSV61115514, COSV61121664; called by muse, mutect2, varscan2
- PRRX2 | c.659G>A p.G220D | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs1448251545, COSV100991224; called by mutect2, varscan2
- RAB40C | c.428C>T p.A143V | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.164); catalogued as rs770929145, COSV50193287; called by mutect2, varscan2
- RABEPK | c.206A>G p.D69G | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.802); catalogued as COSV52334936; called by muse, mutect2, varscan2
- RCSD1 | c.140C>T p.P47L | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750952554, COSV63257970; called by muse, mutect2, varscan2
- RUNX3 | c.844G>T p.A282S | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT tolerated (0.47); PolyPhen benign (0.108); catalogued as COSV58243287; called by muse, mutect2, varscan2
- SDF4 | c.517G>A p.A173T | Missense Mutation (SNP) | VAF 23/156 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs1278594291, COSV55418788, COSV99767880; called by muse, mutect2, varscan2
- TAAR5 | c.819G>A p.M273I | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV57798845; called by muse, mutect2, varscan2
- TANK | c.49C>T p.R17W | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753972171, COSV52044422; called by mutect2, varscan2
- TAS2R1 | c.58G>T p.G20W | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1192288751, COSV66778400; called by muse, mutect2, varscan2
- TMEM177 | c.775G>C p.A259P | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.744); catalogued as COSV55608494; called by muse, mutect2, varscan2
- TRAM1L1 | c.76A>T p.I26F | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as COSV100162426; called by muse, mutect2, varscan2
- TUFM | c.937C>T p.H313Y | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV57948728; called by muse, mutect2, varscan2
- UGT1A10 | c.475A>G p.K159E | Missense Mutation (SNP) | VAF 30/175 reads (17%) | SIFT tolerated (1); PolyPhen probably damaging (0.983); catalogued as COSV60836153; called by muse, mutect2, varscan2
- UMODL1 | c.1264G>A p.E422K | Missense Mutation (SNP) | VAF 9/188 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as COSV61159798; called by muse, mutect2
- ZNF462 | c.7446G>C p.K2482N | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as COSV52935355; called by muse, mutect2, varscan2
- RBBP6 | c.4539_4542del p.K1514Qfs*47 | Frame Shift Del (DEL) | VAF 5/34 reads (15%) | called by mutect2, pindel, varscan2
- TP53 | c.1048_1052del p.L350Gfs*30 | Frame Shift Del (DEL) | VAF 10/41 reads (24%) | called by mutect2, pindel, varscan2
- VIRMA | c.1672del p.H558Ifs*16 | Frame Shift Del (DEL) | VAF 45/167 reads (27%) | called by mutect2, pindel, varscan2
- FAT2 | c.4206C>T p.I1402= | Silent (SNP) | VAF 8/76 reads (11%) | catalogued as rs759316055, COSV55817627; called by mutect2, varscan2
- FZD6 | c.360G>A p.E120= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV62471128; called by mutect2, varscan2
- SCN5A | c.105C>T p.G35= | Silent (SNP) | VAF 3/20 reads (15%) | catalogued as COSV60067264, COSV60067372; called by muse, mutect2
- SVOP | c.1419C>G p.L473= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV54465265, COSV54468507; called by muse, mutect2, varscan2
- TNR | c.1308G>A p.E436= | Silent (SNP) | VAF 17/220 reads (8%) | catalogued as COSV54880234; called by muse, mutect2
- TRMT5 | c.279A>G p.T93= | Silent (SNP) | VAF 19/232 reads (8%) | catalogued as COSV50782058; called by muse, mutect2
- BX119917.1 | n.325A>C | RNA (SNP) | VAF 10/118 reads (8%) | called by muse, mutect2
- MIR371A | n.37G>A | RNA (SNP) | VAF 6/44 reads (14%) | called by mutect2, varscan2
